Gene-level copy-number profile of tumor specimen HCM-CSHL-1262-C19-06A from HCMI case HCM-CSHL-1262-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 65.4 years (23,884 days).
Specimen HCM-CSHL-1262-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 28ff084d-0d68-4441-b3a2-4a8b7e13ec13.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1262-C19-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/2e07ebcc-669b-484b-a7b2-205dd70cb6dc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 875; copy number 2: 11,736; copy number 3: 22,141; copy number 4: 19,547; copy number 5: 2,253; copy number 6: 1,676; copy number 7: 401; copy number 8: 193; copy number 9: 7; copy number 10: 1; copy number 11: 18; copy number 12: 53; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,379,495–20,599,195, 7 genes: HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 674 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:15,325,296–20,183,206, 73 genes, copy number 9–12 (broad region; genes not listed).
- chr8:38,996,754–39,105,445, 1 gene, copy number 11 (within-gene range 2–11): ADAM9.
- chr8:39,106,990–43,674,591, 106 genes, copy number 7–16 (broad region; genes not listed).
- chr8:115,950,511–135,742,495, 275 genes, copy number 7–8 (broad region; genes not listed).
- chr8:137,424,904–145,066,685, 215 genes, copy number 7 (broad region; genes not listed).
- chr14:23,969,874–24,051,377, 2 genes, copy number 7 (within-gene range 4–7): DHRS4L2, AL136419.1.
- chr14:28,829,881–28,968,400, 1 gene, copy number 7 (within-gene range 4–7): LINC02327.
- chr14:28,901,236–28,901,347, 1 gene, copy number 7: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 363. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
